TCGA case TCGA-06-0192 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Henry Ford Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f08280d6-2c80-4dd7-93d3-a0c55f7da5b3

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 58 years; Vital status: Dead; Days to death: 1,185 days (3.2 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 58.2 years (21,243 days); Year of diagnosis: 2007; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 18 days; Days to treatment end: 60 days; Treatment dose: 6,000 cGy; Course number: 1; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 18 days; Days to treatment end: 60 days; Number of cycles: 1; Treatment dose: 150 mg; Prescribed dose: 75; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 96 days; Days to treatment end: 462 days (1.3 years); Number of cycles: 12; Treatment dose: 420 mg; Prescribed dose: 200; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Clinical Trial; Initial disease status: Progressive Disease; Days to treatment start: 725 days (2.0 years); Days to treatment end: 808 days (2.2 years); Number of cycles: 2; Treatment dose: 20 mg/day; Prescribed dose: 20; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Initial disease status: Progressive Disease; Days to treatment start: 725 days (2.0 years); Days to treatment end: 767 days (2.1 years); Number of cycles: 2; Treatment dose: 160 mg; Prescribed dose: 160; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 816 days (2.2 years); Days to treatment end: 1,153 days (3.2 years); Number of cycles: 10; Treatment dose: 873 mg; Prescribed dose: 10; Prescribed dose units: mg/kg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan; Initial disease status: Progressive Disease; Days to treatment start: 816 days (2.2 years); Days to treatment end: 907 days (2.5 years); Number of cycles: 3; Prescribed dose: 125; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 919 days (2.5 years); Days to treatment end: 980 days (2.7 years); Number of cycles: 2; Treatment dose: 140 mg; Prescribed dose: 75; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, Stereotactic/Gamma Knife/SRS; Initial disease status: Progressive Disease; Days to treatment start: 928 days (2.5 years); Days to treatment end: 938 days (2.6 years); Treatment dose: 3,200 cGy; Course number: 2; Number of fractions: 4; Treatment anatomic sites: Locoregional Site.
2. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 59.9 years (21,891 days); Days to diagnosis: 648 days (1.8 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 670 days (1.8 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.

Follow-up (5 entries)
- Days to follow up: 557 days (1.5 years); Disease response: Tumor Free.
- Day 648 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional.
- Days to follow up: 1,185 days (3.2 years); Disease response: With Tumor.
- Karnofsky performance status: 90; Timepoint: Post Adjuvant Therapy.
- Karnofsky performance status: 100; Timepoint: Preoperative.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-06-0192-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
  Slide TCGA-06-0192-01B-01-BS1: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 15; Percent stromal cells: 0.
  Slide TCGA-06-0192-01B-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 25; Percent stromal cells: 0; Percent lymphocyte infiltration: 100.
- Sample TCGA-06-0192-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-06-0192-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: Tumor free; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1: Regimen number: 01.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Regimen number: 03; Therapy regimen: Progression.
- Drug treatment 2, Route of administrations: Route of administration: IV.
- Drug treatment 3: Regimen number: 02; Therapy regimen: Progression.
- Drug treatment 6: Regimen number: 04; Therapy regimen: Progression.
- Drug treatment 7: Regimen number: 02; Pharmaceutical therapy drug name: Cediranib/Placebo; Therapy regimen: Progression.
- Radiation treatment 2: Radiation type other: Fractionated Stereotactic Radiosurgery; Therapy regimen: Progression.
- Follow-up form 2: Tumor status: With tumor; Performance status timing: Post-Adjuvant Therapy.
- Follow-up form 2, New tumor event: New tumor event type: Locoregional Disease; New tumor event surgery: Yes; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,185 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,185 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 648 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-06-0192-01B-01D-0333-01): tumor purity 0.57, ploidy 2.05, whole-genome doublings 0.
